Somatic mutation profile of tumor specimen 0DM1K9 from CCDI case PBBZPT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 16.4 years (6,008 days).
Specimen 0DM1K9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ccc061e-5bc7-4dc0-8a9d-e62985ebc473.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dac7173-390a-4c63-be8a-7aabbe705f8b

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 10 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 10, 5'UTR 4, Intron 3, Frame Shift Ins 2, 3'UTR 2, Nonsense Mutation 2, RNA 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 13/311 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 23/236 reads (10%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 98/384 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARR3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 48/560 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs763163029, COSV57204504; called by muse, mutect2
- ASPN | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs751232189, COSV65015981; called by muse, mutect2, varscan2
- CD1E | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 30/638 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV63770965, COSV63773314; called by muse, mutect2
- CNTN5 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.01); catalogued as COSV99681985; called by muse, mutect2
- CTNND2 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV58928437; called by muse, mutect2
- DAAM1 | c.2120A>G p.N707S | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1398345746, COSV100658135; called by muse, mutect2
- DCAF12L2 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 36/498 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV63580410, COSV63581364; called by muse, mutect2
- DNM1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368427334; called by muse, mutect2
- ESCO1 | c.1079T>G p.V360G | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs374548656; called by muse, mutect2
- FAM71F1 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as rs145647614; called by muse, mutect2
- FGF10 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 45/274 reads (16%) | catalogued as COSV52934780; called by mutect2, varscan2
- FLG | c.9904C>T p.H3302Y | Missense Mutation (SNP) | VAF 56/646 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1250773053, COSV104425342; called by muse, mutect2
- FLG | c.4615A>C p.S1539R | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs536230632, COSV100912077, COSV64237938; called by muse, mutect2
- FNIP1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 17/282 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1488977967, COSV57193641; called by muse, mutect2
- GRM7 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV100735248; called by muse, mutect2
- IL17RC | c.1453C>T p.P485S (on ENST00000295981 / NM_153461.4; = p.P399S on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as rs150602081; called by muse, mutect2, varscan2
- L3MBTL4 | c.1007A>C p.K336T | Missense Mutation (SNP) | VAF 20/426 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV53118685; called by muse, mutect2
- LRRD1 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1225791383; called by muse, mutect2
- NDUFA1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 29/475 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs746256856; called by muse, mutect2
- NEUROD4 | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 63/488 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472737, COSV54474580; called by muse, mutect2, varscan2
- OR8J3 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 27/607 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV56880395; called by muse, mutect2
- RAB40A | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 20/429 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141221975; called by muse, mutect2
- SLC12A5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 44/486 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs555710024; called by muse, mutect2
- ST6GALNAC3 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 23/415 reads (6%) | PolyPhen benign (0); catalogued as rs764007928, COSV60326216; called by muse, mutect2
- SULF1 | c.223dup p.A75Gfs*48 | Frame Shift Ins (INS) | VAF 50/289 reads (17%) | catalogued as rs747316268; called by mutect2, varscan2
- VN1R4 | c.158A>C p.N53T | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60805136; called by muse, mutect2
- WDFY4 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910357445, COSV57442124; called by muse, mutect2
- YTHDF1 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 50/577 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs147453582; called by muse, mutect2
- AP1M1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2
- BCHE | c.1233A>C p.E411D | Missense Mutation (SNP) | VAF 18/465 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- CCDC88A | c.2335dup p.I779Nfs*7 | Frame Shift Ins (INS) | VAF 59/582 reads (10%) | called by mutect2, varscan2
- CD5L | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); called by muse, varscan2
- CLIP1 | c.2746G>A p.E916K (on ENST00000620786 / NM_001247997.1; = p.E905K on NM_002956.2) | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CNBD1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM162B | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- INPP5A | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 15/455 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- INSYN2B | c.1535C>A p.P512H | Missense Mutation (SNP) | VAF 29/531 reads (5%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.789); called by muse, mutect2
- KIAA1549L | c.992C>A p.S331Y (on ENST00000321505; = p.S628Y on NM_012194.3) | Missense Mutation (SNP) | VAF 46/623 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.176); called by muse, mutect2
- KLHL1 | c.1151A>C p.K384T | Missense Mutation (SNP) | VAF 28/529 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2
- LAG3 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC26 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAGEB6B | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 58/630 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- MMP10 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP16 | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 16/543 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2
- NSMAF | c.1476G>T p.K492N | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR2T8 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 22/848 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0.007); called by muse, mutect2
- PCSK2 | c.1774C>T p.H592Y | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, mutect2
- PTN | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 31/513 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- RAD54L2 | c.2358T>G p.D786E | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHROOM4 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- SLC12A5 | c.2227C>A p.P743T (on ENST00000454036 / NM_001134771.2; = p.P720T on NM_020708.5) | Missense Mutation (SNP) | VAF 46/733 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- SNX9 | c.318C>G p.D106E | Missense Mutation (SNP) | VAF 23/408 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.16); called by muse, mutect2
- TOPBP1 | c.4263G>A p.K1421= | Splice Region (SNP) | VAF 12/318 reads (4%) | called by muse, mutect2
- TSGA10 | c.2046C>A p.D682E | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.318); called by muse, mutect2
- TTN | c.69454T>C p.S23152P (on ENST00000591111; = p.S15728P on NM_003319.4) | Missense Mutation (SNP) | VAF 19/512 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.66098T>C p.L22033P (on ENST00000591111; = p.L14609P on NM_003319.4) | Missense Mutation (SNP) | VAF 22/430 reads (5%) | PolyPhen probably damaging (0.988); called by muse, mutect2
- USP29 | c.539A>C p.N180T | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2
- WNT1 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- ZCCHC8 | c.423+1G>C p.X141_splice | Splice Site (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- ZNF816-ZNF321P | c.212T>A p.M71K | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARGLU1 | c.213C>T p.D71= | Silent (SNP) | VAF 35/187 reads (19%) | called by muse, mutect2, varscan2
- GALNT13 | c.39T>G p.T13= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- KRTAP11-1 | c.183T>C p.C61= | Silent (SNP) | VAF 15/342 reads (4%) | called by muse, mutect2
- PCDH10 | c.2967T>C p.T989= | Silent (SNP) | VAF 13/313 reads (4%) | called by muse, mutect2
- PCDHA7 | c.1365C>T p.F455= | Silent (SNP) | VAF 38/546 reads (7%) | catalogued as rs782481189, COSV65342440, COSV65343682; called by muse, mutect2
- SACS | c.3063T>G p.S1021= | Silent (SNP) | VAF 16/534 reads (3%) | catalogued as rs1001262905; called by muse, mutect2
- SVIL | c.6591C>T p.N2197= (on ENST00000355867 / NM_021738.3; = p.N1771= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/316 reads (11%) | catalogued as rs531901887; called by muse, mutect2, varscan2
- THEMIS | c.1116G>A p.A372= | Silent (SNP) | VAF 66/375 reads (18%) | catalogued as COSV64070303; called by muse, mutect2, varscan2
- VAMP7 | c.336A>C p.A112= | Silent (SNP) | VAF 23/548 reads (4%) | called by muse, mutect2
- ZNF716 | c.1311A>G p.K437= | Silent (SNP) | VAF 7/166 reads (4%) | catalogued as rs782173657; called by muse, mutect2
- AC091770.1 | n.209A>C | RNA (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- AC114316.1 | n.1617T>G | RNA (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- CCDC85A | c.*60_*61insCGA | 3'UTR (INS) | VAF 16/148 reads (11%) | called by mutect2, pindel
- CCDC88C | c.-45G>A | 5'UTR (SNP) | VAF 16/76 reads (21%) | called by muse, varscan2
- EXOC3L4 | c.*29G>C | 3'UTR (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- FIGN | c.-44G>A | 5'UTR (SNP) | VAF 27/472 reads (6%) | called by muse, mutect2
- GULP1 | c.843+1707T>G | Intron (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- KLHDC4 | c.1448-63C>T | Intron (SNP) | VAF 8/126 reads (6%) | catalogued as rs983846686; called by muse, mutect2
- MOGAT3 | c.288+49C>T | Intron (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- RTRAF | c.-1C>T | 5'UTR (SNP) | VAF 12/148 reads (8%) | catalogued as rs1166601983; called by muse, mutect2
- TENM1 | c.-60G>T | 5'UTR (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
